Gene-level copy-number profile of tumor specimen TCGA-D5-6532-01A from TCGA case TCGA-D5-6532, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-D5-6532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.24aca1de-2850-4c0b-865d-7fdf29a30a37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6532-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/516f8ad0-f930-40ff-94d8-fc6aac409eb5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 5,027; copy number 2: 49,147; copy number 3: 3,336; copy number 4: 2,137; copy number 6: 164.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6532-01A-11D-1717-01): tumor purity 0.78, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 164 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:31,257,664–32,238,658, 51 genes, copy number 6 (within-gene range 4–6): DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1.
- chr20:37,693,955–38,772,520, 39 genes, copy number 6 (within-gene range 4–6): CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173.
- chr20:45,325,288–46,308,498, 59 genes, copy number 6 (within-gene range 4–6): SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2, WFDC9, WFDC10A, RPS2P7, WFDC11, WFDC10B, WFDC13, MIR3617, SPINT4, HNRNPA1P3, WFDC3, SPINT5P, RNU6ATAC38P, DNTTIP1, UBE2C, TNNC2, SNX21, ACOT8, Metazoa_SRP, ZSWIM3, ZSWIM1, SPATA25, NEURL2, CTSA, AL008726.1, PLTP, AL162458.1, PCIF1, ZNF335, FTLP1, MMP9, SLC12A5-AS1, SLC12A5, NCOA5, RPL13P2, CD40, AL031687.1, CDH22.
- chr20:52,671,735–52,890,386, 4 genes, copy number 6: AL031674.1, AL161945.1, AL121902.1, RPL36P1.
- chr20:53,738,728–54,651,169, 11 genes, copy number 6: AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.

Autosomal genes at a single copy (total copy number 1): 5,017. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
